Gene-level copy-number profile of tumor specimen TCGA-PQ-A6FI-01A from TCGA case TCGA-PQ-A6FI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.3 years (25,672 days).
Specimen TCGA-PQ-A6FI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.83cf49be-cb90-4e49-8636-2e6842a7eec9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PQ-A6FI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9976dc70-5114-44e0-a310-b7cf7e720304

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 339; copy number 2: 25,400; copy number 3: 23,285; copy number 4: 8,915; copy number 5: 1,000; copy number 6: 181; copy number 7: 26; copy number 8: 19; copy number 9: 32; copy number 11: 408; copy number 12: 2; copy number 14: 65; copy number 19: 29; copy number 24: 33; copy number 27: 49; copy number 30: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PQ-A6FI-01A-11D-A31K-01): tumor purity 0.75, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:41,394,595–41,426,504, 1 gene: AC090138.1.
- chr18:71,215,618–71,237,158, 2 genes: AC091691.2, AC091691.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 691 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:12,484,432–12,885,211, 16 genes, copy number 8: TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022.
- chr3:13,052,967–13,053,122, 1 gene, copy number 8: AC069271.1.
- chr4:147,567,606–150,257,438, 32 genes, copy number 9 (within-gene range 4–9): LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, AC105343.2, DCLK2, RNU7-194P.
- chr4:155,173,716–155,737,062, 23 genes, copy number 7: AC097467.3, AC104407.1, NPY2R, AC097467.1, MAP9, YWHAEP4, AC097467.2, AC097467.4, AC097526.1, MTCYBP17, MTND6P17, MTND5P9, MTND4P8, MTND3P3, MTCO3P9, MTATP6P9, MTCO2P9, MTCO1P9, MTND2P33, MTND1P22, AC107208.1, GUCY1A1, AC104083.1.
- chr4:156,634,494–156,971,799, 5 genes, copy number 7–8 (within-gene range 2–8): LINC02272, AC096736.2, AC096736.1, PDGFC, AC092608.1.
- chr6:11,514,192–16,108,593, 62 genes, copy number 19–24 (broad region; genes not listed).
- chr6:18,522,735–23,649,774, 49 genes, copy number 27 (within-gene range 6–27): MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1.
- chr6:50,009,138–50,049,929, 2 genes, copy number 12: DEFB110, DEFB112.
- chr8:33,338,867–38,382,272, 93 genes, copy number 14–30 (within-gene range 4–30) (broad region; genes not listed).
- chr17:26,981,694–35,864,615, 408 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
